Somatic mutation profile of tumor specimen TARGET-10-PAPFKA-09A (aliquot TARGET-10-PAPFKA-09A-01D) from TARGET case TARGET-10-PAPFKA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,301 days).
Specimen TARGET-10-PAPFKA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 289b9478-26b1-4b36-a9c2-a440c2cb21f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFKA-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFKA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70a1b9f0-2269-44bd-b472-2614cff77012

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, RNA 2, 3'Flank 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 15/37 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DCAF8L2 | c.1462G>C p.G488R | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV101445702; called by muse, mutect2, varscan2
- NDST2 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs932615043; called by muse, mutect2, varscan2
- SLFN12L | c.503G>A p.C168Y (on ENST00000260908 / NM_001363830.1; = p.C186Y on NM_001195790.1) | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs533187259; called by muse, mutect2, varscan2
- TDRD6 | c.5966C>T p.S1989L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs150855637; called by muse, varscan2
- BTK | c.347_348insG p.T117Nfs*2 | Frame Shift Ins (INS) | VAF 7/57 reads (12%) | called by mutect2, pindel, varscan2
- GRIA3 | c.2566C>T p.R856C | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, varscan2
- LVRN | c.2521A>G p.I841V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2
- ACAN | c.2439C>A p.P813= | Silent (SNP) | VAF 60/120 reads (50%) | catalogued as rs754184356; called by muse, varscan2
- IGHV1-69 | chr14:106714683 ins GGG | 3'Flank (INS) | VAF 15/46 reads (33%) | called by mutect2, pindel*, varscan2*
- STAU2P1 | n.486G>A | RNA (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- TTC3P1 | n.5971G>A | RNA (SNP) | VAF 11/36 reads (31%) | catalogued as rs772910260; called by muse, mutect2, varscan2
